Surgical pathology report (de-identified scan), TCGA case TCGA-55-8208, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8208-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis

Lung, right upper lobe, resection, with frozen section and touch preparation:

Adenocarcinoma, moderately differentiated.

Specimen integrity: Intact.

Tumor site: Right upper lobe.

Tumor size: 3 cm in greatest dimension.

Tumor focality: Unifocal.

Tumor extension: Limited to lung.

Lymphovascular invasion: Not identified.

neoadjuvant treatment effect : not applicable.

Margins: Bronchial and vascular margins free of involvement.

Negative peribronchial and intraparenchymal nodes (two).

AJCC pathologic stage T1b,N0.

Clinical Information

Right lung mass.

Frozen Section Diagnosis

FSA Right upper lobe wedge biopsy:

Adenocarcinoma.

Gross Description

"FSA." 1c, 1p, all. Submitted "FSA," control tissue.

"NFSA." The specimen consists of a 1.7 x 0.9 x 0.5 cm tan-gray soft fragment. "A," 2p, all.

"B, Right upper lobe lung." The specimen consists of a 114 gram, 15.5 x 12.5 x 4 cm upper lobe of the right lung. The pleural surface is pink-tan with no adhesions. On the medial aspect is a sutured area measuring 2.5 cm long. Adjacent to this is a palpable mass. The pleura at this area is puckered and there is a smooth gray-white area. The pleura is inked black. On sectioning, the underlying mass has a yellow to dark gray focally friable cut surface and measures 3 x 2.5 x 3 cm. The tumor comes to within 1.5 cm of the bronchial margin. The tumor abuts the overlying pleural surface. The remaining specimen is serially sectioned and the cut surface is tan-pink and atelectatic. At the apex there is an area of emphysematous change. No additional masses are noted. Two parabronchial lymph nodes are identified with the largest measuring 1.7 cm. There is a 0.3 cm intraparenchymal lymph node recovered. "B1," bronchial margin; "B2," vascular margin; "B3-B5," representative sections of tumor; "B6," representative sections of lung at apex with emphysematous change; "B7," parabronchial lymph nodes; "B8," intraparenchymal lymph nodes.

[page 2 of 2]
Performing Lab

Testing performed at

Source: NCI Genomic Data Commons file 87965ecf-0000-45a4-9e60-ed5dd198844c (TCGA-55-8208.9E4CF1B8-6628-4791-AA3C-2D7C42B3936B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).